Somatic mutation profile of tumor specimen C3L-00976-03 (aliquot CPT0169530006) from CPTAC case C3L-00976, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 68.1 years (24,864 days).
Specimen C3L-00976-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e05d6180-35b3-4b4a-994c-938c6f97cea3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00976-31 (Blood Derived Normal), aliquot CPT0167130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/945c8450-47a6-4498-8cdd-71edd9c2a2a8

The open-access MAF lists 150 somatic variants for this specimen: 111 protein-altering or splice-affecting, 18 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 18, Intron 11, Frame Shift Del 8, Frame Shift Ins 7, Nonsense Mutation 6, In Frame Del 5, 5'Flank 4, RNA 4, Splice Site 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT17 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 208/857 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs28928897, CM012143, CM970840, COSV60860507; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C8A | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 36/147 reads (24%) | catalogued as rs777495880, COSV63483150; called by muse, mutect2, varscan2
- CCDC115 | c.14A>T p.D5V | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs766377161; called by muse, mutect2, varscan2
- DST | c.5770G>A p.A1924T | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs1425211998; called by muse, mutect2, varscan2
- EFR3B | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373101048; called by muse, mutect2, varscan2
- ELF2 | c.849G>T p.Q283H (on ENST00000379550 / NM_001331036.2; = p.Q223H on NM_006874.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55494490; called by muse, mutect2, varscan2
- EPB42 | c.1487C>T p.T496M (on ENST00000441366 / NM_001114134.2; = p.T526M on NM_000119.3) | Missense Mutation (SNP) | VAF 73/353 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs199787216; called by muse, mutect2, varscan2
- EXOC3L4 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs919870195; called by muse, mutect2, varscan2
- FAM83H | c.1445G>A p.G482D | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs1340186168; called by muse, mutect2
- GABRA2 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765251624; called by muse, mutect2
- HTT | c.3545G>A p.R1182Q | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs1361524056; called by muse, mutect2, varscan2
- INF2 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as rs1350913423; called by muse, mutect2
- IPO11 | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1308465925; called by muse, mutect2, varscan2
- ITGA11 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as rs866595833; called by muse, mutect2, varscan2
- KRTAP13-1 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV62663927; called by muse, mutect2, varscan2
- LINGO3 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302979445; called by muse, mutect2, varscan2
- MYO1H | c.85del p.V29Ffs*40 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as COSV60449549; called by mutect2, pindel, varscan2
- OTOP3 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201806252, COSV60912845; called by muse, mutect2, varscan2
- PATJ | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 40/215 reads (19%) | catalogued as rs1481604265; called by muse, mutect2, varscan2
- RAC1 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV61825124; called by muse, mutect2, varscan2
- RASSF8 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1309009217; called by muse, mutect2, varscan2
- TET2 | c.3788G>A p.C1263Y | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360210418, COSV54406292, COSV54410351; called by muse, mutect2, varscan2
- TMEM102 | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV53439692, COSV53441040; called by muse, mutect2, varscan2
- TULP3 | c.872G>C p.R291P | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV68118243; called by muse, mutect2, varscan2
- UAP1 | c.1354C>G p.P452A | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs1431271456; called by muse, mutect2, varscan2
- VHL | c.540del p.I180Mfs*22 | Frame Shift Del (DEL) | VAF 119/396 reads (30%) | catalogued as CD983006, COSV56552559; called by mutect2, pindel, varscan2
- WASL | c.1485_1487del p.E495del | In Frame Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs750895037; called by pindel, varscan2
- WDR19 | c.1834C>A p.L612M | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.26); catalogued as COSV56462023; called by muse, mutect2, varscan2
- ABCA6 | c.1306A>C p.N436H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ACSF3 | c.673G>C p.G225R | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ADAMTS13 | c.760_766del p.A254Pfs*16 | Frame Shift Del (DEL) | VAF 36/129 reads (28%) | called by mutect2, pindel, varscan2
- ADCY10 | c.540C>G p.N180K | Missense Mutation (SNP) | VAF 151/456 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- AFTPH | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK2 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD23 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AP5M1 | c.367A>C p.I123L | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APAF1 | c.358C>T p.P120S (on ENST00000551964 / NM_181861.2; = p.P109S on NM_001160.3) | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APAF1 | c.359C>T p.P120L (on ENST00000551964 / NM_181861.2; = p.P109L on NM_001160.3) | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAP1 | c.1096_1112del p.Y366Afs*26 | Frame Shift Del (DEL) | VAF 35/194 reads (18%) | called by mutect2, pindel, varscan2
- CARMIL3 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CBFA2T2 | c.1324+2T>C p.X442_splice | Splice Site (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- CDH23 | c.4790dup p.S1598Efs*30 | Frame Shift Ins (INS) | VAF 32/128 reads (25%) | called by mutect2, pindel
- CDS2 | c.1257T>G p.D419E | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHRNA1 | c.1254_1255dup p.S419Kfs*14 (on ENST00000261007 / NM_001039523.3; = p.S394Kfs*14 on NM_000079.4) | Frame Shift Ins (INS) | VAF 33/166 reads (20%) | called by mutect2, pindel, varscan2
- CLBA1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- CMTR1 | c.2371T>G p.F791V | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CNST | c.1762C>G p.L588V | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- COL28A1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- COLGALT1 | c.489+1G>T p.X163_splice | Splice Site (SNP) | VAF 52/193 reads (27%) | called by muse, mutect2, varscan2
- CTDSP2 | c.667del p.Y223Tfs*24 | Frame Shift Del (DEL) | VAF 53/233 reads (23%) | called by mutect2, pindel, varscan2
- DSCAM | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EFNA2 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- EMC1 | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ENDOD1 | c.124_138del p.T42_G46del | In Frame Del (DEL) | VAF 47/300 reads (16%) | called by mutect2, pindel, varscan2
- FAM178B | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FBN2 | c.2228C>A p.P743Q | Missense Mutation (SNP) | VAF 102/532 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXN1 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GRM2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 35/166 reads (21%) | called by muse, mutect2, varscan2
- H3C1 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); called by muse, mutect2
- HADHA | c.88A>T p.T30S | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPAB | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- HNRNPAB | c.629A>T p.K210M | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HOOK3 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.5T>G p.M2R | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INTS14 | c.741dup p.N248* (on ENST00000313182 / NM_001366360.2; = p.N169* on NM_001136043.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 16/117 reads (14%) | called by mutect2, pindel
- IPO11 | c.2224A>G p.T742A | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KDM5A | c.4132_4137del p.E1378_I1379del | In Frame Del (DEL) | VAF 39/282 reads (14%) | called by mutect2, pindel, varscan2
- LYSMD1 | c.448_456del p.H150_L152del | In Frame Del (DEL) | VAF 49/290 reads (17%) | called by mutect2, pindel, varscan2
- MCAM | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MGAM2 | c.5110del p.V1704Cfs*23 | Frame Shift Del (DEL) | VAF 27/153 reads (18%) | called by mutect2, pindel, varscan2
- MIA3 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MOB4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH13 | c.2572_2575dup p.D859Gfs*4 | Frame Shift Ins (INS) | VAF 59/250 reads (24%) | called by mutect2, varscan2
- NAV2 | c.1639C>A p.P547T (on ENST00000396087 / NM_001244963.2; = p.P524T on NM_145117.5) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NDUFS8 | c.109+7A>G | Splice Region (SNP) | VAF 109/531 reads (21%) | called by muse, mutect2, varscan2
- NFKBIZ | c.1750C>G p.L584V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP13 | c.2813G>T p.R938I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR14C36 | c.521A>C p.Q174P | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR2D2 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OR51G1 | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE2A | c.1109T>C p.F370S | Missense Mutation (SNP) | VAF 71/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PDE9A | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PIAS2 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PIK3CB | c.1404del p.E468Dfs*6 | Frame Shift Del (DEL) | VAF 17/86 reads (20%) | called by mutect2, pindel
- PITPNA | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCD3 | c.2222C>A p.A741D | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- PLCD3 | c.2221G>C p.A741P | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- PLG | c.1513T>C p.W505R | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PMVK | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 121/284 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPIA | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRRG3 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RANBP2 | c.1106dup p.L369Ffs*6 | Frame Shift Ins (INS) | VAF 112/486 reads (23%) | called by mutect2, pindel, varscan2
- REV3L | c.7650G>T p.Q2550H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RNPEP | c.1757A>G p.E586G | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ROBO3 | c.3774C>A p.Y1258* | Nonsense Mutation (SNP) | VAF 47/238 reads (20%) | called by muse, mutect2, varscan2
- SAV1 | c.420dup p.D141* | Frame Shift Ins (INS) | VAF 62/182 reads (34%) | called by mutect2, varscan2
- SRBD1 | c.1935G>A p.M645I | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- STT3A | c.991T>C p.Y331H | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TONSL | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TPP1 | c.995T>A p.L332H | Missense Mutation (SNP) | VAF 102/403 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIP6 | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TSC1 | c.585C>G p.Y195* | Nonsense Mutation (SNP) | VAF 92/300 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.91940C>T p.P30647L (on ENST00000591111; = p.P23223L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | PolyPhen benign (0.434); called by muse, varscan2
- UBE4A | c.1655C>G p.P552R (on ENST00000252108 / NM_001204077.2; = p.P559R on NM_004788.4) | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- UGT1A1 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 94/403 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VIM | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 30/424 reads (7%) | called by muse, mutect2
- WEE2 | c.561dup p.G188Rfs*22 | Frame Shift Ins (INS) | VAF 24/168 reads (14%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF624 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF800 | c.1857_1859del p.R619_C620delinsS | In Frame Del (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- ZNF837 | c.378_384del p.R126Sfs*279 | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | called by mutect2, pindel, varscan2
- CHST1 | c.798C>T p.N266= | Silent (SNP) | VAF 55/256 reads (21%) | called by muse, mutect2, varscan2
- CUX2 | c.1686G>T p.V562= | Silent (SNP) | VAF 76/299 reads (25%) | called by muse, mutect2, varscan2
- DNAAF1 | c.951C>A p.I317= | Silent (SNP) | VAF 94/388 reads (24%) | catalogued as rs147108125; called by muse, mutect2, varscan2
- DND1 | c.531G>A p.A177= | Silent (SNP) | VAF 69/402 reads (17%) | called by muse, mutect2, varscan2
- EMC1 | c.291G>A p.V97= | Silent (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- ITIH6 | c.3921C>T p.P1307= | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as rs753873564; called by muse, mutect2, varscan2
- KRT80 | c.195G>A p.L65= | Silent (SNP) | VAF 55/214 reads (26%) | catalogued as rs1026533700; called by muse, mutect2, varscan2
- MAGEB18 | c.84G>T p.T28= | Silent (SNP) | VAF 73/145 reads (50%) | catalogued as COSV100305630, COSV57464623; called by muse, mutect2, varscan2
- MYO1E | c.1041G>A p.Q347= | Silent (SNP) | VAF 56/257 reads (22%) | called by muse, mutect2, varscan2
- NLE1 | c.915C>G p.A305= | Silent (SNP) | VAF 72/275 reads (26%) | called by muse, mutect2, varscan2
- NLRC3 | c.2577C>T p.C859= | Silent (SNP) | VAF 73/309 reads (24%) | catalogued as rs534592582, COSV57094904; called by muse, mutect2, varscan2
- PCDHA8 | c.1089T>C p.A363= | Silent (SNP) | VAF 70/412 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.2646G>A p.Q882= | Silent (SNP) | VAF 137/712 reads (19%) | called by muse, mutect2, varscan2
- PKHD1 | c.4857T>C p.G1619= | Silent (SNP) | VAF 50/259 reads (19%) | called by muse, mutect2, varscan2
- RPE | c.198C>T p.F66= | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as COSV63278070; called by muse, mutect2, varscan2
- SMYD1 | c.861C>A p.L287= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- TNIP1 | c.1083T>A p.R361= | Silent (SNP) | VAF 58/329 reads (18%) | called by muse, mutect2, varscan2
- TOMM40L | c.225A>T p.G75= | Silent (SNP) | VAF 114/338 reads (34%) | called by muse, mutect2, varscan2
- AC009237.3 | n.451G>T | RNA (SNP) | VAF 53/202 reads (26%) | called by muse, mutect2, varscan2
- ADAM9 | c.*998A>G | 3'UTR (SNP) | VAF 44/188 reads (23%) | called by muse, mutect2, varscan2
- ADARB2 | c.1683-128G>A | Intron (SNP) | VAF 57/236 reads (24%) | called by muse, mutect2, varscan2
- ANO2 | c.10+946G>T | Intron (SNP) | VAF 46/229 reads (20%) | called by muse, mutect2, varscan2
- AP001830.2 | n.303A>G | RNA (SNP) | VAF 22/92 reads (24%) | catalogued as rs909820606; called by muse, mutect2, varscan2
- ATXN7L1 | c.355+27141G>A | Intron (SNP) | VAF 35/157 reads (22%) | called by muse, mutect2, varscan2
- CIRBP | chr19:1268366 G>A | 5'Flank (SNP) | VAF 17/45 reads (38%) | catalogued as rs1307616363; called by muse, mutect2, varscan2
- CMPK2 | chr2:6865881 C>T | 5'Flank (SNP) | VAF 45/162 reads (28%) | catalogued as rs1276086954; called by muse, mutect2, varscan2
- COL14A1 | c.5312-769C>T | Intron (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- EP400P1 | n.622G>A | RNA (SNP) | VAF 46/197 reads (23%) | called by muse, mutect2, varscan2
- FGF13 | c.403-32116C>A | Intron (SNP) | VAF 44/81 reads (54%) | called by muse, mutect2, varscan2
- LINC00470 | n.1361-2541A>G | Intron (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- MIR382 | n.45C>T | RNA (SNP) | VAF 55/154 reads (36%) | catalogued as rs377201140; called by muse, mutect2, varscan2
- MMP7 | c.484+9_484+15delinsA | Intron (DEL) | VAF 38/226 reads (17%) | called by pindel, varscan2*
- NEK6 | chr9:124257707 G>A | 5'Flank (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- PEX10 | c.-2C>T | 5'UTR (SNP) | VAF 20/68 reads (29%) | catalogued as rs776078242; called by muse, mutect2, varscan2
- RASGEF1B | c.438+51G>A | Intron (SNP) | VAF 104/337 reads (31%) | catalogued as rs780768156; called by muse, mutect2, varscan2
- SORD | c.101-34C>A | Intron (SNP) | VAF 10/45 reads (22%) | called by mutect2, varscan2
- SPAG9 | c.590+517A>G | Intron (SNP) | VAF 53/239 reads (22%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1165-160T>C | Intron (SNP) | VAF 60/203 reads (30%) | called by muse, mutect2, varscan2
- VEZT | chr12:95217800 C>T | 5'Flank (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
